Surgical pathology report (de-identified scan), TCGA case TCGA-D6-8568, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma), tissue source site Greater Poland Cancer Center, specimen TCGA-D6-8568-01A (Primary Tumor).

Unit in charge: [REDACTED]

Physician in charge: [REDACTED]

Clinical diagnosis (suspicion) **Tumour of the larynx, left side.**

Date of admission: [REDACTED] (urgency: Standard)

Material:

1) Material: larynx, Tumour of the larynx: Please examine the marked margin. Method of collection: Collection of specimens for laboratory examination

Histopathological diagnosis:

Examination performed on: 1 [REDACTED]

Carcinoma planoepitheliale keratodes invasivum laryngis G2, pT2. (8070/3 T- 24100)*

Invasive keratinizing squamous carcinoma of the larynx

Assistant: [REDACTED]

Preliminary result:

Examination performed on: [REDACTED]

Carcinoma planoepitheliale invasivum keratodes.

the tumour infiltrates the left side of the subglottic region, vessels and nerve stems.

Surgical incision lines off cancer invaded area. Sinus histiocytosis lymphonodorum No I

(Delphan)

Final reply to be given after full material is developed

Macroscopic description:

Surgical specimen sized 9x7x5,5cm with the hyoid bone and a 2 cm section of the trachea. On the left side side of the subglottic region, tumour sized 2,2x2,3x0,9cm infiltrating into the subglottic and supraglottic region.

Assistant: [REDACTED] Pathologist: : [REDACTED]

CONTACT YOUR DOCTOR WITH THIS REPORT!

Source: NCI Genomic Data Commons file f878d985-18ab-4f96-b9b7-0dc25ec44e18 (TCGA-D6-8568.6F7BD35E-6494-4EAD-BD09-C1BCAFF06E93.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).